HCMI case HCM-BROD-0794-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e76d41a-9cf7-4114-b48a-84571c929f22

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1975; Vital status: Dead; Days to death: 1,444 days (4.0 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Signet ring cell carcinoma (the primary disease): ICD-O-3 morphology code: 8490/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 41.4 years (15,107 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Epirubicin + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: EOX; Days to treatment start: 7 days.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Metastatic signet ring cell carcinoma: ICD-O-3 morphology code: 8490/6; ICD-10 code: C78.6; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 45.0 years (16,428 days); Days to diagnosis: 1,321 days (3.6 years).
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Capecitabine + Epirubicin + Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: EOX; Days to treatment start: 7 days; Days to treatment end: 1,286 days (3.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Leucovorin Calcium; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Days to treatment start: 7 days; Days to treatment end: 1,286 days (3.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 7 days; Days to treatment end: 1,286 days (3.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 7 days; Days to treatment end: 1,286 days (3.5 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 1,429 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- ERBB2 (IHC): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Reflux treatment type: Proton Pump Inhibitors; Risk factor treatment: Yes; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 38 kg; Height: 158 cm; BMI: 15.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-BROD-0794-C16-06B: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0794-C16-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0794-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
